Surgical pathology report (de-identified scan), TCGA case TCGA-BJ-A28T, project TCGA-THCA (Thyroid Carcinoma), tissue source site University of Pittsburgh, specimen TCGA-BJ-A28T-01A (Primary Tumor).

PATIENT HISTORY:

CHIEF COMPLAINT/PRE-OP/POST-OP DIAGNOSIS: Papillary thyroid cancer
PROCEDURE: Total thyroid
SPECIFIC CLINICAL QUESTION: Not answered
OUTSIDE TISSUE DIAGNOSIS: Not answered
PRIOR MALIGNANCY: Not answered
CHEMO RADIATION: Not answered
ORGAN TRANSPLANT: Not answered
IMMUNOSUPPRESSION: Not answered
OTHER DISEASES: Not answered

1CD-0-3

carcinoma, papillary, thyroid

8260/3

Site: thyroid C73.9

/w
5/25/11**FINAL DIAGNOSIS:****PART 1: THYROID GLAND, TOTAL THYROIDECTOMY (15 GRAMS)-****A. TWO FOCI OF PAPILLARY THYROID CARCINOMA, CONVENTIONAL TYPE:**

- a. 1.3 CM, RIGHT LOBE (See comment).
b. 0.1 CM, LEFT LOBE.

Collection Date:

B. EXTRATHYROIDAL EXTENSION IS ABSENT.**C. CARCINOMA IS 0.1 CM FROM MARGIN.****D. METASTATIC PAPILLARY THYROID CARCINOMA, UP TO 0.28 CM, IN TWO LYMPH NODES (2/3).****E. CHRONIC LYMPHOCYTIC THYROIDITIS.****F. T1b N1a.****PART 2: CENTRAL COMPARTMENT LYMPH NODES, DISSECTION-****A. METASTATIC PAPILLARY THYROID CARCINOMA, 0.1 CM, IN ONE LYMPH NODE (1/6).****B. EXTRANODAL SPREAD IS ABSENT.****COMMENT:**

The carcinoma is associated with extensive fibrosis and was decalcified as part of routine histologic evaluation. Decalcification precludes additional molecular analysis.

CASE SYNOPSIS:**SYNOPTIC DATA - PRIMARY THYROID TUMORS****SPECIMEN TYPE:**

Total Thyroidectomy

TUMOR SITE:

Right Lobe, Left Lobe

TUMOR FOCALITY:

Multifocal

TUMOR SIZE (largest nodule):

Greatest Dimension: 1.3 cm

HISTOLOGIC TYPE:**

Papillary carcinoma

PRIMARY TUMOR (pT):

pT1b

REGIONAL LYMPH NODES (pN):

pN1a

Number of regional lymph nodes examined: 9

Number of regional lymph nodes involved: 3

EXTRANODAL EXTENSION:

Not identified

DISTANT METASTASIS (pM):

Not applicable

EXTRATHYROIDAL EXTENSION:

Not identified

MARGINS:

Margins uninvolved by carcinoma

Distance of invasive carcinoma to closest margin: 1 mm

LYMPH-VASCULAR INVASION:

Indeterminate

ADDITIONAL PATHOLOGIC FINDINGS:

Thyroiditis

Source: NCI Genomic Data Commons file 9d33fb36-7a51-4b53-aba7-0d8a70e5ca3f (TCGA-BJ-A28T.B989C4A6-271C-4AC4-A55A-3011C7C6ED05.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).